Somatic mutation profile of cancer-model specimen HCM-WCMC-0504-C18-85A (3D Organoid, passage 15; aliquot HCM-WCMC-0504-C18-85A-01D-A83U-36), derived from the primary tumor of HCMI case HCM-WCMC-0504-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 58.6 years (21,389 days).
Specimen HCM-WCMC-0504-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 15.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a9bcbaa-a958-4a53-97af-a6517bb6b6e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0504-C18-10B (Blood Derived Normal), aliquot HCM-WCMC-0504-C18-10B-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6c917b9-9936-4560-b932-cb3be3d4234c

The open-access MAF lists 1,462 somatic variants for this specimen: 1,097 protein-altering or splice-affecting, 306 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 793, Silent 306, Frame Shift Del 193, Frame Shift Ins 47, Nonsense Mutation 33, Intron 32, Splice Region 12, 3'UTR 11, In Frame Del 10, 5'Flank 8, Splice Site 6, 5'UTR 3.

Variants (750 of 1,462; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as rs730880056; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 258/550 reads (47%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DMD | c.10453del p.L3485* | Frame Shift Del (DEL) | VAF 270/655 reads (41%) | catalogued as rs886043375, CD073610; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYRK1A | c.461del p.K154Sfs*11 | Frame Shift Del (DEL) | VAF 90/393 reads (23%) | catalogued as rs797044521; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS1 | c.3554dup p.S1186Vfs*10 | Frame Shift Ins (INS) | VAF 172/421 reads (41%) | catalogued as rs750714387; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AARD | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 379/1176 reads (32%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs542421964, COSV65599658; called by muse, mutect2, varscan2
- ABCC2 | c.4085G>T p.G1362V | Missense Mutation (SNP) | VAF 179/351 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64987105; called by muse, mutect2, varscan2
- ABCD3 | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs200013693, COSV59867013; called by muse, mutect2, varscan2
- ABCG4 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 261/763 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs752059482, COSV56641872; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 242/519 reads (47%) | SIFT deleterious, low confidence (0); catalogued as rs773242958, COSV99865371; called by muse, mutect2, varscan2
- AC004997.1 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 215/493 reads (44%) | SIFT deleterious, low confidence (0.03); catalogued as rs574213079; called by muse, mutect2, varscan2
- AC011462.1 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 230/474 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs761915209; called by muse, mutect2, varscan2
- ACTRT2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 146/297 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs189197365; called by muse, mutect2, varscan2
- ACVR2B | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 297/576 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1241037610, COSV61702516; called by muse, varscan2
- ADAMTS10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 236/499 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs111234410; called by muse, mutect2, varscan2
- ADAMTS3 | c.1067del p.L356* | Frame Shift Del (DEL) | VAF 224/561 reads (40%) | catalogued as rs1424429467; called by mutect2, pindel, varscan2
- ADARB2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 206/497 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs144565549; called by muse, mutect2, varscan2
- ADARB2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 440/869 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1322029552, COSV67228331; called by muse, mutect2, varscan2
- ADGRA3 | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 267/590 reads (45%) | catalogued as rs1433768320; called by muse, mutect2, varscan2
- ADGRB3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 168/395 reads (43%) | catalogued as COSV65402251; called by muse, varscan2
- ADNP | c.2594del p.K865Sfs*49 | Frame Shift Del (DEL) | VAF 221/540 reads (41%) | catalogued as COSV100823746; called by mutect2, pindel, varscan2
- ADSS2 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs150012791; called by muse, mutect2, varscan2
- AGRN | c.5416C>T p.R1806W | Missense Mutation (SNP) | VAF 266/598 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs757150379; called by muse, varscan2
- AK8 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 103/297 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV53761217, COSV53761951; called by muse, mutect2, varscan2
- ALPI | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 283/735 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.542); catalogued as rs750554208; called by muse, mutect2, varscan2
- ANGPTL2 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 222/441 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs760636806; called by muse, mutect2, varscan2
- ANGPTL7 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 310/595 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100815977; called by muse, mutect2, varscan2
- AP3B2 | c.2710A>G p.S904G (on ENST00000261722; = p.S898G on NM_004644.5) | Missense Mutation (SNP) | VAF 195/457 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1257261195; called by muse, mutect2, varscan2
- APC2 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 149/1089 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1273537617; called by muse, mutect2, varscan2
- APEH | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 165/339 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs774564457; called by muse, mutect2, varscan2
- AQP2 | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 240/518 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52229740; called by muse, mutect2, varscan2
- AR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 309/656 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as rs962089572; called by muse, mutect2, varscan2
- ARFGEF1 | c.5228G>A p.R1743H | Missense Mutation (SNP) | VAF 60/716 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs753689074; called by muse, mutect2
- ARFGEF1 | c.4655del p.P1552Hfs*6 | Frame Shift Del (DEL) | VAF 152/539 reads (28%) | catalogued as COSV51619799; called by mutect2, pindel, varscan2
- ARFGEF2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 241/488 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs748227723, COSV64212843; called by muse, mutect2, varscan2
- ARHGAP20 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 85/227 reads (37%) | catalogued as rs1449319024, COSV52814832; called by muse, mutect2, varscan2
- ARHGEF10 | c.2197G>A p.V733M (on ENST00000398564; = p.V708M on NM_014629.4) | Missense Mutation (SNP) | VAF 270/825 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as rs769602938; called by muse, mutect2, varscan2
- ARHGEF11 | c.4151dup p.Q1385Sfs*3 | Frame Shift Ins (INS) | VAF 253/634 reads (40%) | catalogued as rs1423067261; called by mutect2, pindel, varscan2
- ARHGEF15 | c.1366del p.R456Vfs*21 | Frame Shift Del (DEL) | VAF 328/786 reads (42%) | catalogued as rs1567676744; called by mutect2, pindel, varscan2
- ARID1A | c.4214T>A p.L1405* | Nonsense Mutation (SNP) | VAF 90/836 reads (11%) | catalogued as COSV61380981; called by muse, mutect2, varscan2
- ARSL | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 252/512 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.376); catalogued as rs761135869; called by muse, mutect2, varscan2
- ARVCF | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 406/819 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs759894174, COSV99599298; called by muse, mutect2, varscan2
- ARVCF | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 421/902 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as rs374797711; called by muse, mutect2, varscan2
- ASXL1 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 324/661 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs747065583, COSV60109567; called by muse, mutect2, varscan2
- ASXL2 | c.4285G>A p.V1429I | Missense Mutation (SNP) | VAF 174/377 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754392619, COSV55464427; called by muse, mutect2, varscan2
- ATM | c.7223C>T p.S2408L | Missense Mutation (SNP) | VAF 209/481 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs730881315, COSV53738904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.713del p.G238Efs*60 | Frame Shift Del (DEL) | VAF 190/408 reads (47%) | catalogued as COSV63111162; called by mutect2, varscan2
- ATP1B1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1228659582; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1251C>T p.Y417= | Splice Region (SNP) | VAF 196/364 reads (54%) | catalogued as rs1426120425, CM135387; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 56/488 reads (11%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AVPR1A | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 350/744 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV54548053; called by muse, mutect2, varscan2
- B3GNT9 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 354/674 reads (53%) | catalogued as rs371081032; called by muse, mutect2, varscan2
- BAHCC1 | c.4541C>T p.A1514V | Missense Mutation (SNP) | VAF 263/552 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1294495291, COSV57026991; called by muse, mutect2, varscan2
- BATF2 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 339/740 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs1347786641; called by muse, mutect2, varscan2
- BCL2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 135/1141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373065228; called by muse, mutect2, varscan2
- BCOR | c.4261C>T p.R1421C (on ENST00000378444 / NM_001123385.2; = p.R1387C on NM_017745.6) | Missense Mutation (SNP) | VAF 420/918 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as rs746716983, COSV60712517; called by muse, mutect2, varscan2
- BCS1L | c.1008G>A p.R336= | Splice Region (SNP) | VAF 188/380 reads (49%) | catalogued as rs1314813758; called by muse, mutect2, varscan2
- BICRA | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 318/633 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs868510387; called by muse, mutect2, varscan2
- BMP7 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 210/438 reads (48%) | catalogued as rs769591631; called by muse, mutect2, varscan2
- BMP7 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 198/448 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs776230892, COSV67782177; called by muse, mutect2, varscan2
- BMP8B | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 263/775 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs766684364; called by muse, mutect2, varscan2
- BOP1 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 503/1528 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as rs1027468097; called by muse, mutect2, varscan2
- BTBD19 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 247/542 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1271408937; called by muse, mutect2, varscan2
- C15orf62 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 359/808 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1456080294; called by muse, mutect2, varscan2
- C17orf107 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.678); catalogued as rs763019934; called by muse, varscan2
- C17orf107 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 371/823 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1186314661, COSV53419313; called by muse, mutect2
- C4A | c.3574G>A p.A1192T | Missense Mutation (SNP) | VAF 366/1270 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.923); catalogued as rs759121287, COSV71177765; called by muse, mutect2, varscan2
- C6orf47 | c.481del p.E161Nfs*22 | Frame Shift Del (DEL) | VAF 485/1247 reads (39%) | catalogued as rs1396655057; called by mutect2, pindel, varscan2
- CACNA1S | c.5218C>A p.P1740T | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.081); catalogued as COSV62944939; called by muse, varscan2
- CAND2 | c.3260G>A p.R1087Q (on ENST00000456430 / NM_001162499.2; = p.R970Q on NM_012298.3) | Missense Mutation (SNP) | VAF 225/503 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781451160, COSV55990798; called by muse, mutect2, varscan2
- CASP8 | c.1380del p.K461Nfs*10 (on ENST00000432109 / NM_033355.3; = p.K478Nfs*10 on NM_001228.4) | Frame Shift Del (DEL) | VAF 232/618 reads (38%) | catalogued as COSV51859087; called by mutect2, pindel, varscan2
- CCDC151 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 173/398 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1229956522; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2
- CCDC40 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 284/649 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376363442; ClinVar: uncertain significance; called by muse, mutect2
- CCDC54 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 195/444 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1267316139; called by muse, mutect2, varscan2
- CCDC85A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 448/907 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs760317264; called by muse, mutect2, varscan2
- CCNA1 | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV55222951; called by muse, mutect2, varscan2
- CCNG1 | c.337A>G p.R113G | Missense Mutation (SNP) | VAF 64/522 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.863); catalogued as rs746289913; called by muse, mutect2, varscan2
- CD248 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 367/788 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs146691747; called by muse, mutect2, varscan2
- CD300LG | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 181/386 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs373605771, COSV99517330; called by muse, mutect2, varscan2
- CDC123 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760876745; called by muse, mutect2, varscan2
- CDCA7 | c.571C>A p.L191I (on ENST00000347703 / NM_145810.3; = p.L270I on NM_031942.5) | Missense Mutation (SNP) | VAF 220/519 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100143807; called by muse, mutect2, varscan2
- CDH13 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 189/423 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs771595136; called by muse, mutect2, varscan2
- CDH4 | c.1781del p.P594Rfs*35 | Frame Shift Del (DEL) | VAF 191/476 reads (40%) | catalogued as rs1367432489; called by mutect2, pindel, varscan2
- CDH6 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 253/602 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746180154; called by muse, mutect2, varscan2
- CDK10 | c.935C>T p.A312V (on ENST00000353379 / NM_052988.5; = p.A241V on NM_052987.4) | Missense Mutation (SNP) | VAF 190/418 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as rs780139658; called by muse, mutect2, varscan2
- CDK5R2 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 253/484 reads (52%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.448); catalogued as rs1429667871; called by muse, mutect2, varscan2
- CECR2 | c.703T>C p.S235P (on ENST00000342247 / NM_001290047.2; = p.S72P on NM_001290046.1) | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs1353859755; called by muse, mutect2, varscan2
- CELSR3 | c.5381G>A p.R1794Q | Missense Mutation (SNP) | VAF 314/700 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1028524336; called by muse, mutect2, varscan2
- CENPB | c.1312dup p.E438Gfs*16 | Frame Shift Ins (INS) | VAF 79/250 reads (32%) | catalogued as rs748211874; called by mutect2, varscan2
- CEP131 | c.1721T>C p.M574T (on ENST00000269392 / NM_001319228.2; = p.M571T on NM_014984.4) | Missense Mutation (SNP) | VAF 218/506 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs762629509; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 86/207 reads (42%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 173/424 reads (41%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CHD3 | c.3124T>C p.S1042P | Missense Mutation (SNP) | VAF 146/282 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV100391133; called by muse, mutect2, varscan2
- CHD8 | c.7337C>T p.T2446M (on ENST00000646647 / NM_001170629.2; = p.T2167M on NM_020920.4) | Missense Mutation (SNP) | VAF 285/614 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.105); catalogued as rs763909898; called by muse, mutect2, varscan2
- CHERP | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 535/1058 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs775337450; called by muse, mutect2, varscan2
- CHERP | c.21del p.D8Mfs*26 | Frame Shift Del (DEL) | VAF 354/871 reads (41%) | catalogued as COSV99550254; called by mutect2, pindel, varscan2
- CIC | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 379/791 reads (48%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.137); catalogued as rs1201027582; called by muse, mutect2, varscan2
- CILP2 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 354/707 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs137977776; called by muse, varscan2
- CLCN6 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 308/605 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56740416; called by muse, mutect2, varscan2
- CLDN18 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 170/378 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs756497056; called by muse, varscan2
- CLMN | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 160/362 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.232); catalogued as rs145924471; called by muse, mutect2, varscan2
- CLSTN3 | c.2858del p.P953Hfs*106 | Frame Shift Del (DEL) | VAF 179/517 reads (35%) | catalogued as rs758841384; called by pindel, varscan2
- CNDP1 | c.1522T>C p.*508Qext*9 | Nonstop Mutation (SNP) | VAF 78/301 reads (26%) | catalogued as COSV62594003; called by muse, mutect2, varscan2
- CNDP2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 146/393 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs200600524; called by muse, mutect2
- CNTNAP1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 205/437 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52848213; called by muse, mutect2, varscan2
- COL27A1 | c.1911T>C p.G637= | Splice Region (SNP) | VAF 156/351 reads (44%) | catalogued as rs1272426516; called by muse, varscan2
- COL4A3 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 160/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67420154; called by muse, mutect2, varscan2
- COL7A1 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs868465415, COSV60391056; called by muse, mutect2, varscan2
- COPS6 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 190/433 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100385164; called by muse, mutect2, varscan2
- CPSF1 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 240/1050 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs1371004405; called by muse, mutect2, varscan2
- CPZ | c.1024C>T p.R342C (on ENST00000360986 / NM_001014447.3; = p.R331C on NM_003652.3) | Missense Mutation (SNP) | VAF 255/553 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755742622, COSV100248635; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 138/357 reads (39%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRELD2 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 365/791 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1423277655; called by mutect2, varscan2
- CRISPLD1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 124/548 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.292); catalogued as COSV51547938; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 94/235 reads (40%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CSF1R | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 210/469 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1318254419, COSV53831916; called by muse, mutect2, varscan2
- CTNND2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 290/587 reads (49%) | catalogued as COSV100479151; called by muse, mutect2, varscan2
- CUEDC1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 376/708 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327648739; called by muse, mutect2, varscan2
- CUX2 | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 197/431 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55628641; called by muse, mutect2, varscan2
- CXCL2 | c.308del p.N103Mfs*50 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | catalogued as rs745343380; called by mutect2, pindel, varscan2
- CXCR2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 243/470 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199777583; called by muse, mutect2, varscan2
- DACT3 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 503/996 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs552110358; called by muse, mutect2, varscan2
- DAGLB | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 152/339 reads (45%) | catalogued as rs562661517, CM142359; called by muse, mutect2, varscan2
- DBNDD2 | c.562del p.Q188Sfs*12 | Frame Shift Del (DEL) | VAF 252/633 reads (40%) | catalogued as rs1320987043; called by mutect2, pindel, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 385/777 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DCHS2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 369/820 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311246649, COSV100253150; called by muse, varscan2
- DDX43 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 312/654 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.057); catalogued as COSV100946233; called by muse, mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 94/172 reads (55%) | catalogued as rs778036194; called by mutect2, varscan2
- DGKK | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 123/403 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV65709145; called by muse, mutect2, varscan2
- DIAPH3 | c.973dup p.C325Lfs*29 (on ENST00000400324 / NM_001042517.2; = p.C62Lfs*29 on NM_030932.3) | Frame Shift Ins (INS) | VAF 102/264 reads (39%) | catalogued as rs766969544; called by mutect2, varscan2
- DIPK1C | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 358/682 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs762337921; called by muse, mutect2, varscan2
- DIPK2A | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 288/614 reads (47%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.855); catalogued as rs1235739562; called by muse, mutect2, varscan2
- DISP1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 163/348 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs765609888, COSV52657862; called by muse, mutect2, varscan2
- DLGAP2 | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 398/1241 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70096210; called by muse, mutect2, varscan2
- DLX5 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 310/678 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV99756721; called by muse, mutect2, varscan2
- DLX5 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 195/423 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.055); catalogued as rs1460070802; called by muse, mutect2, varscan2
- DNAH1 | c.9122G>A p.R3041H | Missense Mutation (SNP) | VAF 307/640 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs546452557, COSV101326364; called by muse, mutect2, varscan2
- DNAH14 | c.8143G>A p.A2715T (on ENST00000445597; = p.A3518T on NM_001367479.1) | Missense Mutation (SNP) | VAF 234/502 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs369673460, COSV99071038; called by muse, mutect2, varscan2
- DNAH17 | c.4076G>A p.R1359Q | Missense Mutation (SNP) | VAF 215/466 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375265574; called by muse, mutect2, varscan2
- DNAH9 | c.10596del p.G3533Dfs*40 | Frame Shift Del (DEL) | VAF 26/245 reads (11%) | catalogued as COSV52345258; called by mutect2, pindel, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 220/478 reads (46%) | catalogued as rs774662919; called by mutect2, varscan2
- DOT1L | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 247/552 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs781606489, COSV67107693; called by muse, mutect2, varscan2
- DPY19L1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 113/264 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs200098469, COSV60584869; called by muse, mutect2, varscan2
- DTX2 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 386/966 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs199598165; called by muse, varscan2
- DUOX1 | c.4568dup p.G1524Wfs*26 | Frame Shift Ins (INS) | VAF 237/628 reads (38%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DYNC1H1 | c.9737A>G p.D3246G | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs1291221765; called by muse, mutect2, varscan2
- DYNC1H1 | c.11989C>T p.R3997W | Missense Mutation (SNP) | VAF 68/519 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399236395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1566_1568del p.N522del | In Frame Del (DEL) | VAF 127/253 reads (50%) | catalogued as rs779190112; called by pindel, varscan2
- E2F2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 95/222 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764211496; called by muse, mutect2, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 125/429 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, varscan2
- ECPAS | c.3983C>T p.A1328V | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs1263750941; called by muse, varscan2
- EFR3A | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 140/483 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs536114379; called by muse, mutect2, varscan2
- EIF2B3 | c.508A>G p.M170V | Missense Mutation (SNP) | VAF 185/368 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64518863; called by muse, mutect2, varscan2
- EIF4G3 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 213/425 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51694889; called by muse, mutect2, varscan2
- EIF5B | c.293del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 51/347 reads (15%) | catalogued as rs769971529; called by mutect2, varscan2
- ELAVL3 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 326/630 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.03); catalogued as rs748019175; called by muse, varscan2
- ELP4 | c.747del p.K249Nfs*6 (on ENST00000350638; = p.K248Nfs*6 on NM_019040.5) | Frame Shift Del (DEL) | VAF 98/249 reads (39%) | catalogued as COSV63351931; called by mutect2, pindel, varscan2
- EMILIN2 | c.2767G>A p.V923I | Missense Mutation (SNP) | VAF 188/439 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs780356221, COSV99598141; called by muse, mutect2, varscan2
- EPHB6 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 259/558 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291135944, COSV100844294; called by muse, mutect2, varscan2
- EPS15 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs930419380; called by muse, mutect2, varscan2
- ERBB4 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 63/674 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs561236916, COSV53525744; called by muse, mutect2
- ERCC2 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 314/665 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs768677952, COSV67263648; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 116/366 reads (32%) | catalogued as rs753821453; called by mutect2, varscan2
- ETV5 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 303/652 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV60506181; called by muse, mutect2, varscan2
- EVL | c.874_876del p.K292del (on ENST00000402714 / NM_001330221.2; = p.K294del on NM_016337.3) | In Frame Del (DEL) | VAF 183/462 reads (40%) | catalogued as rs1200397092; called by pindel, varscan2
- EYA1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.123); catalogued as rs145219836, COSV58158058; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 141/429 reads (33%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM131A | c.768del p.S257Afs*48 (on ENST00000310585; = p.S288Afs*48 on NM_144635.5) | Frame Shift Del (DEL) | VAF 401/822 reads (49%) | catalogued as COSV55602091; called by mutect2, varscan2
- FAM47C | c.2167G>A p.V723I | Missense Mutation (SNP) | VAF 237/524 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs782084099; called by muse, mutect2, varscan2
- FAM78B | c.692del p.P231Lfs*4 | Frame Shift Del (DEL) | VAF 265/641 reads (41%) | catalogued as rs763715884; called by mutect2, pindel, varscan2
- FAM83H | c.2787dup p.V930Rfs*41 | Frame Shift Ins (INS) | VAF 379/1206 reads (31%) | catalogued as rs781931295; called by mutect2, varscan2
- FARP1 | c.2888_2890del p.F963del | In Frame Del (DEL) | VAF 126/287 reads (44%) | catalogued as rs1390774650; called by pindel, varscan2
- FBRSL1 | c.2874del p.A959Pfs*45 | Frame Shift Del (DEL) | VAF 207/518 reads (40%) | catalogued as rs893226416; called by mutect2, pindel, varscan2
- FBXL8 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 102/700 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs746141895, COSV50459763; called by muse, mutect2, varscan2
- FBXO47 | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65242876; called by muse, mutect2, varscan2
- FEM1A | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 313/681 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.108); catalogued as rs146137689; called by muse, varscan2
- FGF14 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 375/797 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs750276006, COSV65945025; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 247/535 reads (46%) | catalogued as rs777980924; called by mutect2, varscan2
- FLG | c.3685G>A p.G1229S | Missense Mutation (SNP) | VAF 169/348 reads (49%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs377533309, COSV100911121; called by muse, mutect2, varscan2
- FLNA | c.5098G>A p.V1700M (on ENST00000369850 / NM_001110556.2; = p.V1692M on NM_001456.3) | Missense Mutation (SNP) | VAF 321/608 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs782351877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNA | c.1978A>G p.M660V | Missense Mutation (SNP) | VAF 249/670 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs782510387; called by muse, mutect2, varscan2
- FOXF2 | c.919_921dup p.D307dup | In Frame Ins (INS) | VAF 387/775 reads (50%) | catalogued as rs1200364411; called by mutect2, pindel, varscan2
- FOXQ1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 303/656 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1256631452, COSV57259630; called by muse, mutect2, varscan2
- FRMPD4 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 345/739 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.047); catalogued as COSV101041737; called by muse, mutect2, varscan2
- FYTTD1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 137/324 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs761860704, COSV54084497; called by muse, mutect2, varscan2
- FZD9 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 328/689 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1189855467; called by muse, mutect2, varscan2
- GAL3ST2 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 47/623 reads (8%) | catalogued as rs1340703846; called by muse, mutect2
- GALNT16 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 186/402 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778928386; called by muse, mutect2, varscan2
- GDAP1L1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs750968488, COSV100697527, COSV61158883; called by muse, mutect2, varscan2
- GNRH2 | c.73C>T p.H25Y | Missense Mutation (SNP) | VAF 337/650 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55662251; called by muse, mutect2, varscan2
- GPATCH8 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 314/671 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs749705021; called by muse, mutect2, varscan2
- GPR37 | c.357del p.W120Gfs*51 | Frame Shift Del (DEL) | VAF 298/817 reads (36%) | catalogued as COSV58258793; called by mutect2, pindel, varscan2
- GRAMD4 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 203/454 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1208069675; called by muse, mutect2, varscan2
- GRIN2B | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 91/698 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101663199; called by muse, mutect2, varscan2
- GRM1 | c.446del p.P149Qfs*11 | Frame Shift Del (DEL) | VAF 206/550 reads (37%) | catalogued as rs1207726214, COSV51123015, COSV99267293; called by mutect2, pindel, varscan2
- GRM7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 143/321 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1025403472, COSV100735833, COSV63173475, COSV99066173; called by muse, varscan2
- GTPBP1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 177/557 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs758734440; called by muse, mutect2, varscan2
- GYG2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 376/819 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs147564323; called by muse, mutect2, varscan2
- HAP1 | c.1536G>A p.M512I (on ENST00000310778 / NM_001367460.1; = p.M460I on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781860680; called by muse, mutect2, varscan2
- HAPLN4 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 503/1038 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as rs1442894214; called by muse, mutect2, varscan2
- HGS | c.1447del p.A483Rfs*2 | Frame Shift Del (DEL) | VAF 307/808 reads (38%) | catalogued as rs1555699517, COSV100230656; called by mutect2, pindel, varscan2
- HIPK1 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 193/619 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1290706585; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 32/298 reads (11%) | catalogued as rs199474609; called by mutect2, varscan2
- HMBS | c.264T>C p.N88= | Splice Region (SNP) | VAF 29/438 reads (7%) | catalogued as rs750889050, COSV53830504; called by muse, mutect2
- HMCN1 | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 152/338 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144448119; called by muse, mutect2, varscan2
- HOXC13 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 473/925 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1470777937; called by muse, mutect2, varscan2
- HOXD13 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 178/600 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1166185321, COSV66832816; called by muse, mutect2, varscan2
- HS6ST2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 465/983 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV63718366; called by muse, mutect2, varscan2
- HSPA1L | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 241/509 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs375290879; called by muse, mutect2, varscan2
- HSPG2 | c.1834G>T p.G612C | Missense Mutation (SNP) | VAF 274/583 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768946900; called by muse, mutect2, varscan2
- HTRA4 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 159/738 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV56761105; called by muse, mutect2, varscan2
- HUWE1 | c.8516C>T p.A2839V | Missense Mutation (SNP) | VAF 197/435 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV53341138; called by muse, mutect2, varscan2
- HYDIN | c.4232C>T p.T1411M | Missense Mutation (SNP) | VAF 141/317 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs763237651, COSV66830824; called by muse, mutect2, varscan2
- IFNGR1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/461 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.304); catalogued as rs1018508960, COSV62989357; called by muse, mutect2
- IGF2R | c.2660C>T p.T887M | Missense Mutation (SNP) | VAF 223/463 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752875889; called by muse, mutect2, varscan2
- IGHV5-51 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 234/499 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1555541242; called by muse, mutect2, varscan2
- IGSF11 | c.1190G>A p.R397Q (on ENST00000393775 / NM_001015887.3; = p.R396Q on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 170/492 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as rs759484762; called by muse, mutect2, varscan2
- IHH | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 391/742 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs3731880; called by muse, mutect2, varscan2
- IL17RC | c.2253_2254del p.R751Sfs*14 (on ENST00000295981 / NM_153461.4; = p.R665Sfs*14 on NM_032732.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 350/906 reads (39%) | catalogued as rs752617588; called by pindel, varscan2
- IL31RA | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 166/370 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.142); catalogued as COSV51681363; called by muse, mutect2, varscan2
- ING1 | c.1103G>A p.G368D | Missense Mutation (SNP) | VAF 279/565 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58170934; called by muse, mutect2, varscan2
- INSM2 | c.1144del p.A382Pfs*9 | Frame Shift Del (DEL) | VAF 394/902 reads (44%) | catalogued as COSV51898306; called by mutect2, pindel, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 58/188 reads (31%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQSEC3 | c.2854G>A p.E952K (on ENST00000538872 / NM_001170738.2; = p.E649K on NM_015232.1) | Missense Mutation (SNP) | VAF 309/701 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as rs781815118; called by muse, mutect2, varscan2
- IRF4 | c.963del p.D322Tfs*62 | Frame Shift Del (DEL) | VAF 320/796 reads (40%) | catalogued as COSV66705190; called by mutect2, pindel, varscan2
- ISL2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 238/486 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756779917; called by muse, mutect2, varscan2
- KCNH3 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 335/707 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57789911; called by muse, mutect2, varscan2
- KCNK15 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 431/817 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs970735520; called by muse, mutect2, varscan2
- KCNN1 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 190/408 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1338697202; called by muse, mutect2, varscan2
- KCNQ2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 38/1428 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1064797286; ClinVar: uncertain significance; called by muse, mutect2
- KCNV1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 276/854 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52085727; called by muse, mutect2, varscan2
- KHDC3L | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 57/527 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.4); catalogued as rs748502124; called by muse, varscan2
- KHDC4 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 118/285 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs760168909, COSV100850749, COSV64164546; called by muse, varscan2
- KIAA2013 | c.1380del p.L461Cfs*74 | Frame Shift Del (DEL) | VAF 291/754 reads (39%) | catalogued as COSV64860737; called by mutect2, pindel, varscan2
- KIDINS220 | c.5065A>G p.S1689G | Missense Mutation (SNP) | VAF 326/669 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs749481172; called by muse, mutect2, varscan2
- KIF26B | c.5168C>T p.A1723V | Missense Mutation (SNP) | VAF 149/1181 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as rs778660763; called by muse, mutect2, varscan2
- KIF5B | c.1647dup p.R550Tfs*4 | Frame Shift Ins (INS) | VAF 216/563 reads (38%) | catalogued as rs745430029; called by mutect2, pindel, varscan2
- KIT | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 214/479 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs767174569, COSV55386928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC7B | c.362C>A p.A121E (on ENST00000395676; = p.A762E on NM_138433.5) | Missense Mutation (SNP) | VAF 484/1017 reads (48%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.057); catalogued as rs777583262; called by muse, mutect2, varscan2
- KLHL35 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 407/806 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as rs759314666; called by muse, mutect2, varscan2
- KLHL41 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 157/343 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs868095411; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 447/1161 reads (39%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KRT74 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 382/753 reads (51%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as rs763304950, COSV99977475; called by muse, mutect2, varscan2
- KRTAP10-7 | c.388A>G p.S130G | Missense Mutation (SNP) | VAF 411/780 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs233307, COSV59112209; called by muse, mutect2, varscan2
- KRTAP5-10 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 170/341 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as rs752243956, COSV64794097; called by muse, mutect2, varscan2
- KSR2 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 422/828 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.46); catalogued as rs1022500773, COSV60392602; called by muse, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 401/1106 reads (36%) | catalogued as rs782221297; called by mutect2, pindel, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 98/249 reads (39%) | catalogued as COSV60222740; called by pindel, varscan2
- LHX4 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 210/477 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs761944467, COSV99761922; called by muse, mutect2, varscan2
- LIN37 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 147/348 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs374032128; called by muse, mutect2, varscan2
- LIPG | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 147/295 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM127990; called by muse, mutect2, varscan2
- LOXHD1 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 262/572 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916954027, COSV59662442; called by muse, varscan2
- LRFN2 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 352/729 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs746243295, COSV57827102; called by muse, mutect2, varscan2
- LRP2 | c.10234G>A p.A3412T | Missense Mutation (SNP) | VAF 188/392 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147922851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC14 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 373/1181 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs745462286, COSV52883430; called by muse, mutect2, varscan2
- LRRCC1 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 220/748 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as rs781467429; called by muse, mutect2, varscan2
- LTA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 377/785 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.702); catalogued as rs377059622; called by muse, mutect2, varscan2
- LYST | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 195/390 reads (50%) | catalogued as rs756867102, COSV67703931; called by muse, mutect2, varscan2
- MADD | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 237/525 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs140505071; called by muse, mutect2, varscan2
- MAP3K5 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 219/458 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as rs766760055, COSV62886601; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 239/510 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1254983501; called by muse, mutect2, varscan2
- MATN2 | c.1072del p.T358Rfs*5 | Frame Shift Del (DEL) | VAF 172/599 reads (29%) | catalogued as rs1319426383; called by mutect2, pindel, varscan2
- MBD2 | c.320A>G p.D107G | Missense Mutation (SNP) | VAF 102/288 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1242663921; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 113/231 reads (49%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCOLN2 | c.747G>A p.T249= | Splice Region (SNP) | VAF 124/246 reads (50%) | catalogued as rs1377342424, COSV99393689; called by muse, mutect2, varscan2
- MED12 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 202/455 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV61354946; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 716/1014 reads (71%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- METTL24 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 171/452 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as rs1372498754, COSV58821820; called by muse, mutect2, varscan2
- MFAP2 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 224/514 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs756106741, COSV100977637; called by muse, mutect2, varscan2
- MICU3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 406/1330 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.024); catalogued as COSV58849276; called by muse, varscan2
- MMP24 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1200868074; called by muse, mutect2, varscan2
- MMP25 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1488946616; called by muse, mutect2
- MROH6 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 577/1837 reads (31%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs745639075; called by muse, mutect2
- MTMR3 | c.2815T>A p.S939T | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100070829; called by muse, mutect2, varscan2
- MUC5B | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 237/483 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs764598061; called by muse, mutect2, varscan2
- MYB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs777923027, COSV57196169, COSV57200862; called by muse, mutect2, varscan2
- MYB | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV57199131; called by muse, mutect2, varscan2
- MYH6 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 61/505 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV62449342; called by muse, mutect2, varscan2
- MYO18A | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 171/360 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs571276684; called by muse, mutect2, varscan2
- MYO5C | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 140/295 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs539722733, COSV55906722; called by muse, mutect2, varscan2
- MYOZ3 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 103/903 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as rs766224195, COSV51739562; called by muse, mutect2, varscan2
- NANOS3 | c.355G>A p.V119I (on ENST00000397555; = p.V138I on NM_001098622.2) | Missense Mutation (SNP) | VAF 391/817 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs368073921; called by muse, mutect2, varscan2
- NAP1L1 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.498); catalogued as rs149910881; called by muse, mutect2
- NDUFAF7 | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 228/423 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs993134186; called by muse, mutect2, varscan2
- NES | c.4610G>A p.G1537D | Missense Mutation (SNP) | VAF 276/592 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV63960951; called by muse, mutect2, varscan2
- NFE2L3 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 172/380 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs1408770675, COSV50227360; called by muse, mutect2, varscan2
- NKX2-1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 139/1083 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.702); catalogued as CM102270; called by muse, mutect2, varscan2
- NKX6-2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 245/544 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371870778; called by muse, mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 189/485 reads (39%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH2 | c.3959C>T p.A1320V | Missense Mutation (SNP) | VAF 172/565 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.334); catalogued as COSV99863649; called by muse, mutect2, varscan2
- NPAS3 | c.2317G>A p.A773T (on ENST00000356141 / NM_001164749.2; = p.A741T on NM_022123.3) | Missense Mutation (SNP) | VAF 202/388 reads (52%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs767138301; called by muse, mutect2, varscan2
- NPHP1 | c.1807G>T p.D603Y (on ENST00000393272 / NM_207181.4; = p.D604Y on NM_000272.5) | Missense Mutation (SNP) | VAF 146/274 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772249010, COSV100338256, COSV104413681, COSV57211830; called by muse, mutect2, varscan2
- NPHP3 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs889394540; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPHP4 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 190/435 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs865792284; called by muse, mutect2, varscan2
- NPRL2 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 288/607 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV99204563; called by muse, mutect2, varscan2
- NRXN3 | c.1856G>A p.R619H (on ENST00000335750 / NM_001330195.2; = p.R246H on NM_004796.6) | Missense Mutation (SNP) | VAF 307/607 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752029799, COSV59717743; called by muse, mutect2, varscan2
- NT5C2 | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 118/271 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100583307; called by muse, mutect2, varscan2
- NT5DC3 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs775554546; called by muse, mutect2, varscan2
- NTN4 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 101/349 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.186); catalogued as rs267603725; called by muse, mutect2, varscan2
- NXPE2 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 301/627 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1456654444; called by muse, mutect2, varscan2
- OPLAH | c.3175G>A p.V1059M | Missense Mutation (SNP) | VAF 96/1195 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1175213897, COSV70679528; called by muse, mutect2
- OPN1MW | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1557159071; called by mutect2, varscan2
- OPRK1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 52/902 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs756086278, COSV55571084; called by muse, mutect2
- OR10G6 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 224/474 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1007339903, COSV61022254; called by muse, mutect2
- OR1E2 | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 244/558 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs559638155; called by muse, mutect2, varscan2
- OR1N2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65460257; called by muse, mutect2
- OR2C1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 231/497 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs780752599, COSV59240960; called by muse, mutect2, varscan2
- OR2T35 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 210/552 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs542809469; called by muse, mutect2, varscan2
- OR4C46 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs144006817; called by muse, mutect2, varscan2
- OR4C6 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV100051636; called by muse, mutect2, varscan2
- OR4K14 | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 133/447 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs369896383; called by muse, mutect2, varscan2
- OTOP1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 330/972 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.229); catalogued as rs568093695, COSV99587842; called by muse, varscan2
- OVCH1 | c.277A>G p.S93G | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs779763167; called by muse, mutect2, varscan2
- P2RY12 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs763135685; called by muse, mutect2, varscan2
- PAK2 | c.1451A>G p.D484G | Missense Mutation (SNP) | VAF 130/323 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs761446581; called by muse, mutect2, varscan2
- PALMD | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 227/474 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.207); catalogued as rs556174782, COSV54163638; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 155/387 reads (40%) | catalogued as rs1484598500; called by mutect2, pindel, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 226/562 reads (40%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PCDH17 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 277/572 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932145; called by muse, mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHA5 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 409/825 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs782637737; called by muse, mutect2, varscan2
- PCDHA7 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 295/584 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV65346505, COSV65348202; called by muse, mutect2, varscan2
- PCDHA7 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 228/447 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV100970845, COSV65335104; called by muse, mutect2, varscan2
- PCDHB2 | c.1685T>C p.F562S | Missense Mutation (SNP) | VAF 459/1047 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1357663714; called by muse, mutect2, varscan2
- PCDHB8 | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 215/1023 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99176895; called by muse, mutect2, varscan2
- PCDHGA3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 241/447 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as rs370532251, COSV53990751; called by muse, mutect2, varscan2
- PCDHGB1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 267/587 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV53959753; called by muse, mutect2, varscan2
- PCM1 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 155/588 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746281426; called by muse, mutect2, varscan2
- PDE1C | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs775455105; called by muse, mutect2, varscan2
- PDE4DIP | c.6953T>C p.L2318P | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553635563; called by muse, mutect2, varscan2
- PFDN2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 47/481 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs770416144; called by muse, mutect2, varscan2
- PGS1 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 169/341 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs368547832; called by muse, mutect2, varscan2
- PHKA2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 421/867 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs774266693; called by muse, mutect2, varscan2
- PHLDA2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 572/1045 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0.099); catalogued as COSV56540919; called by muse, varscan2
- PHLDB1 | c.3767G>A p.S1256N | Missense Mutation (SNP) | VAF 122/234 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs781845616; called by muse, mutect2, varscan2
- PHYKPL | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 228/477 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1166151709; called by muse, mutect2, varscan2
- PHYKPL | c.1054dup p.I352Nfs*24 | Frame Shift Ins (INS) | VAF 210/540 reads (39%) | catalogued as rs762471696; called by mutect2, pindel, varscan2
- PIP4K2C | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 137/272 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs543501661; called by muse, mutect2, varscan2
- PITPNM2 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 391/831 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs376647562; called by muse, mutect2, varscan2
- PIWIL1 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as rs377411680; called by muse, mutect2, varscan2
- PLD2 | c.111C>T p.A37= | Splice Region (SNP) | VAF 45/381 reads (12%) | catalogued as rs201025028; called by muse, mutect2, varscan2
- PLD3 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1017787217; called by muse, mutect2, varscan2
- PLEKHG3 | c.864G>A p.P288= (on ENST00000394691; = p.P344= on NM_001308147.2) | Splice Region (SNP) | VAF 153/348 reads (44%) | catalogued as rs1566706800, COSV55977532; called by muse, mutect2, varscan2
- PLEKHG5 | c.749C>T p.A250V (on ENST00000400915 / NM_001042663.3; = p.A213V on NM_020631.6) | Missense Mutation (SNP) | VAF 276/604 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs367543633; ClinVar: uncertain significance; called by muse, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 168/392 reads (43%) | catalogued as rs746342377; called by mutect2, varscan2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 377/967 reads (39%) | catalogued as rs953293505; called by mutect2, pindel, varscan2
- PLXND1 | c.2767G>A p.V923M | Missense Mutation (SNP) | VAF 303/676 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs762979740; called by muse, mutect2, varscan2
- PNCK | c.52C>T p.R18C (on ENST00000340888 / NM_001366975.1; = p.R101C on NM_001039582.3) | Missense Mutation (SNP) | VAF 349/732 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs1349409547, COSV61744026; called by muse, varscan2
- POGK | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 256/550 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs752253527, COSV63311164; called by muse, mutect2, varscan2
- POLG2 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 220/457 reads (48%) | catalogued as rs782004592; called by muse, mutect2, varscan2
- POLN | c.212del p.K71Rfs*6 | Frame Shift Del (DEL) | VAF 125/284 reads (44%) | catalogued as rs760971697; called by mutect2, pindel, varscan2
- POP1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 60/766 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as rs1364201080; called by muse, mutect2
- POU4F1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 218/415 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.114); catalogued as rs763743520; called by muse, mutect2, varscan2
- POU4F2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 162/607 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55585867, COSV99850583; called by muse, mutect2, varscan2
- POU4F3 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 394/806 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs148830499; called by muse, mutect2, varscan2
- PPP1CC | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 185/403 reads (46%) | catalogued as rs866672821, COSV58582427; called by muse, varscan2
- PPP2R1A | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 340/737 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs769334090, COSV59043773; called by muse, mutect2, varscan2
- PPP3CB | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 256/563 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs758464886; called by muse, mutect2, varscan2
- PRAME | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 328/736 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs1330513615; called by muse, mutect2, varscan2
- PRDM2 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 253/511 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs151171355, COSV52450854; called by muse, mutect2, varscan2
- PRDM6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1173169991, COSV68335207; called by muse, mutect2, varscan2
- PRDM9 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 163/412 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104393150; called by muse, mutect2, varscan2
- PRICKLE2 | c.567C>T p.C189= (on ENST00000295902; = p.C133= on NM_198859.4) | Splice Region (SNP) | VAF 174/370 reads (47%) | catalogued as rs764057934; called by muse, mutect2, varscan2
- PRKCG | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 322/689 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1398372035; called by muse, mutect2, varscan2
- PRKCH | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 50/371 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760739355; called by muse, mutect2, varscan2
- PRR32 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 144/495 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs924131397; called by muse, mutect2, varscan2
- PRR5L | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 239/562 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs780212600; called by muse, mutect2, varscan2
- PRRT2 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 235/515 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs777959783; called by muse, mutect2, varscan2
- PRSS8 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 288/763 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs765697014; called by muse, mutect2, varscan2
- PTGDR2 | c.865G>A p.V289I | Missense Mutation (SNP) | VAF 464/1016 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as rs1299567960; called by muse, mutect2, varscan2
- PTPN1 | c.923del p.P308Hfs*27 | Frame Shift Del (DEL) | VAF 355/779 reads (46%) | catalogued as COSV65410014; called by mutect2, pindel, varscan2
- PTPN14 | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 358/768 reads (47%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.998); catalogued as rs370626715; called by muse, mutect2, varscan2
- PTPRQ | c.5297C>T p.A1766V (on ENST00000616559; = p.A1724V on NM_001145026.2) | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs778313896; called by muse, varscan2
- PTPRS | c.4774G>A p.G1592S | Missense Mutation (SNP) | VAF 213/440 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571743236, COSV53612076; called by muse, mutect2, varscan2
- PTPRT | c.3661C>A p.L1221I | Missense Mutation (SNP) | VAF 237/483 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61967317; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 171/406 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV104383893; called by muse, mutect2, varscan2
- RAB44 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 277/580 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs796830000; called by muse, mutect2, varscan2
- RALGPS1 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 189/421 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.89); catalogued as rs1051049786, COSV52221362, COSV52225068; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1106A>G p.H369R (on ENST00000408927 / NM_001100427.2; = p.H370R on NM_021159.5) | Missense Mutation (SNP) | VAF 146/357 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as rs375361617; called by muse, varscan2
- RAPSN | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as rs776841111; called by muse, mutect2, varscan2
- RBM28 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.631); catalogued as rs199999804; called by muse, mutect2, varscan2
- RBSN | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 222/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773059145, COSV53793370; called by muse, mutect2, varscan2
- RECK | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 200/428 reads (47%) | catalogued as rs376008783; called by muse, mutect2, varscan2
- RERE | c.1433del p.P478Rfs*8 | Frame Shift Del (DEL) | VAF 166/436 reads (38%) | catalogued as COSV61946838; called by mutect2, pindel, varscan2
- RGS21 | c.405dup p.L136Tfs*4 | Frame Shift Ins (INS) | VAF 108/279 reads (39%) | catalogued as rs746536278; called by mutect2, pindel, varscan2
- RHOBTB2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 282/796 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331435808; called by muse, mutect2, varscan2
- RIMBP2 | c.235del p.L79Wfs*15 | Frame Shift Del (DEL) | VAF 304/730 reads (42%) | catalogued as rs1286661920; called by mutect2, pindel, varscan2
- RIMKLB | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 265/597 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs181443607; called by muse, mutect2, varscan2
- RIMS1 | c.3935A>G p.Q1312R | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.885); catalogued as rs1008642456; called by muse, mutect2, varscan2
- RIMS2 | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 45/642 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as rs769411792, COSV68113453; called by muse, mutect2
- RIPPLY3 | c.514del p.E172Rfs*50 | Frame Shift Del (DEL) | VAF 273/537 reads (51%) | catalogued as rs1227193558; called by mutect2, varscan2
- RNF111 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 660/660 reads (100%) | catalogued as COSV62084267, COSV62087885; called by muse, mutect2, varscan2
- RNF8 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 128/310 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs149686329; called by muse, mutect2, varscan2
- RPL10L | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 269/508 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs764186971, COSV100022301; called by muse, mutect2, varscan2
- RPL35 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 208/444 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as COSV100780829; called by mutect2, varscan2
- RPP40 | c.745A>G p.S249G | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs1024956577; called by muse, mutect2
- RTCB | c.736dup p.M246Nfs*6 | Frame Shift Ins (INS) | VAF 262/522 reads (50%) | catalogued as rs771992011; called by mutect2, varscan2
- RTP5 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 208/687 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746911206, COSV58322198; called by muse, varscan2
- RUNX1 | c.1139A>G p.Y380C (on ENST00000344691 / NM_001001890.3; = p.Y407C on NM_001754.5) | Missense Mutation (SNP) | VAF 354/699 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55878223; called by muse, mutect2, varscan2
- SCARF2 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 275/491 reads (56%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs1281268302; called by muse, mutect2, varscan2
- SENP7 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766434336, COSV58610954; called by muse, mutect2, varscan2
- SEPTIN4 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 240/529 reads (45%) | catalogued as rs778224980, COSV57898700; called by muse, mutect2, varscan2
- SERTAD2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 269/553 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as rs767846380; called by muse, mutect2, varscan2
- SETD1B | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 295/630 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.895); catalogued as COSV57349665; called by mutect2, varscan2
- SETD2 | c.7355C>T p.S2452L | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775780402, COSV57434569; called by muse, mutect2, varscan2
- SETDB2 | c.640T>C p.C214R | Missense Mutation (SNP) | VAF 202/454 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1566169400; called by muse, mutect2, varscan2
- SF3A2 | c.995del p.P332Qfs*114 | Frame Shift Del (DEL) | VAF 272/628 reads (43%) | catalogued as rs771822076; called by mutect2, pindel, varscan2
- SHANK2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 161/362 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs782210973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIRT6 | c.1024del p.H342Tfs*7 | Frame Shift Del (DEL) | VAF 283/687 reads (41%) | catalogued as rs769236924; called by mutect2, pindel, varscan2
- SLC16A11 | c.122T>C p.V41A (on ENST00000308009; = p.V17A on NM_153357.3) | Missense Mutation (SNP) | VAF 494/1045 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs763026139; called by muse, mutect2, varscan2
- SLC17A7 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 221/452 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55549614, COSV55549814; called by muse, mutect2, varscan2
- SLC22A12 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 330/632 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs1384341957, COSV60572317; called by muse, varscan2
- SLC25A48 | c.420C>T p.D140= | Splice Region (SNP) | VAF 193/360 reads (54%) | catalogued as rs777873378, COSV99192030; called by muse, mutect2, varscan2
- SLC26A3 | c.353del p.F118Sfs*16 | Frame Shift Del (DEL) | VAF 110/285 reads (39%) | catalogued as rs752963526; called by mutect2, pindel, varscan2
- SLC27A3 | c.1624C>T p.R542W (on ENST00000271857; = p.R414W on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 455/956 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs182081931; called by muse, mutect2, varscan2
- SLC2A5 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 173/404 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs371167568; called by muse, mutect2, varscan2
- SLC44A3 | c.1657A>G p.M553V (on ENST00000271227 / NM_001114106.3; = p.M505V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 166/369 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs756041627, COSV54731577; called by muse, varscan2
- SLC5A2 | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 331/696 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs149680639, CM087262; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 131/517 reads (25%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC7A9 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs143999252; called by muse, varscan2
- SLC9A2 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 316/659 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs747383702; called by muse, mutect2, varscan2
- SLC9A3 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 42/432 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as rs200347051; called by muse, mutect2
- SLCO2A1 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 234/472 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1275389088, COSV60490091; called by muse, mutect2, varscan2
- SMARCA4 | c.2854del p.E952Kfs*5 | Frame Shift Del (DEL) | VAF 111/470 reads (24%) | catalogued as COSV100759350; called by mutect2, pindel, varscan2
- SMARCA5 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 169/322 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs759214495, COSV51645986; called by muse, mutect2, varscan2
- SMARCB1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 28/652 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs767791254, COSV54093241; called by muse, mutect2
- SMARCB1 | c.1010C>T p.P337L (on ENST00000263121; = p.P383L on NM_003073.5) | Missense Mutation (SNP) | VAF 483/1009 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); catalogued as COSV51954125, COSV51955614; called by muse, mutect2, varscan2
- SMARCC2 | c.3043C>A p.Q1015K | Missense Mutation (SNP) | VAF 279/628 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV53237034; called by mutect2, varscan2
- SMC3 | c.127del p.Y43Mfs*69 | Frame Shift Del (DEL) | VAF 85/287 reads (30%) | catalogued as rs1466680694; called by mutect2, pindel, varscan2
- SMPD4 | c.1613G>A p.R538H (on ENST00000409031 / NM_017951.4; = p.R509H on NM_017751.4) | Missense Mutation (SNP) | VAF 181/386 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs1325049882, COSV99045471; called by muse, mutect2, varscan2
- SNRNP70 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 165/337 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1465556467; called by muse, mutect2, varscan2
- SNX18 | c.1245del p.A416Pfs*42 | Frame Shift Del (DEL) | VAF 314/746 reads (42%) | catalogued as rs779304883; called by mutect2, pindel, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 142/305 reads (47%) | catalogued as rs768873484; called by mutect2, varscan2
- SNX32 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 211/458 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs374515235; called by muse, mutect2, varscan2
- SOCS1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 472/954 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.455); catalogued as rs749027399; called by muse, mutect2, varscan2
- SOCS1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 118/992 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs750257680, COSV59659332; called by muse, mutect2, varscan2
- SORBS1 | c.1072dup p.R358Kfs*5 (on ENST00000361941 / NM_001034954.2; = p.R194Kfs*5 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 242/613 reads (39%) | catalogued as rs1210654256; called by mutect2, pindel, varscan2
- SORL1 | c.6479C>T p.T2160M | Missense Mutation (SNP) | VAF 213/491 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs372203239; called by muse, mutect2, varscan2
- SOX3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 416/900 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs760010000, COSV65168425; called by muse, mutect2, varscan2
- SPATA16 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 122/315 reads (39%) | catalogued as rs745984261; called by muse, mutect2, varscan2
- SPATA3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 471/985 reads (48%) | SIFT deleterious, low confidence (0); catalogued as rs1353305177; called by muse, mutect2, varscan2
- SPATA7 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs768713530, COSV99248530; called by muse, mutect2, varscan2
- SPATS2L | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 210/457 reads (46%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1194126462, COSV62354372; called by muse, mutect2, varscan2
- SPEG | c.6913G>A p.E2305K | Missense Mutation (SNP) | VAF 393/796 reads (49%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.622); catalogued as rs754379643, COSV56665975; called by muse, mutect2, varscan2
- SPNS3 | c.766A>G p.K256E | Missense Mutation (SNP) | VAF 148/323 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV61071633; called by muse, mutect2, varscan2
- SPOCK1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 222/509 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs768946526; called by muse, mutect2, varscan2
- SPPL2B | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 356/741 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.093); catalogued as rs529477585; called by muse, mutect2, varscan2
- SPRY4 | c.697G>A p.A233T (on ENST00000434127 / NM_001127496.3; = p.A256T on NM_030964.4) | Missense Mutation (SNP) | VAF 371/754 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.745); catalogued as rs761651255, COSV100702209, COSV100702211; called by muse, mutect2, varscan2
- SRF | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 248/517 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs763406737; called by muse, varscan2
- SSH1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 238/491 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222844460, COSV58457131; called by muse, mutect2, varscan2
- SSH1 | c.714del p.A239Rfs*25 | Frame Shift Del (DEL) | VAF 160/389 reads (41%) | catalogued as COSV58460169; called by mutect2, pindel, varscan2
- STK32C | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 249/514 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs754644339, COSV53838008; called by muse, mutect2, varscan2
- STOX2 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 225/528 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772535660, COSV100408744; called by muse, mutect2, varscan2
- STRC | c.739del p.L247Sfs*76 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1567120304; called by mutect2, varscan2
- STXBP4 | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 177/418 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs143730464; called by muse, mutect2, varscan2
- SULF2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1273104352, COSV63417734; called by muse, mutect2, varscan2
- SYCE2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 229/459 reads (50%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.058); catalogued as COSV53366806; called by muse, mutect2, varscan2
- SYCP2 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 127/283 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1195019660, COSV62765650; called by muse, mutect2, varscan2
- SYNE2 | c.3664C>T p.R1222W | Missense Mutation (SNP) | VAF 161/320 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs773994020, COSV100648495; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAS1R2 | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 288/622 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.535); catalogued as rs376688216; called by muse, mutect2, varscan2
- TCHH | c.5721G>T p.K1907N | Missense Mutation (SNP) | VAF 214/624 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV64275500; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 160/323 reads (50%) | catalogued as rs763321097; called by mutect2, varscan2
- TEKT1 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs199498472, COSV58624074; called by muse, mutect2, varscan2
- TEX15 | c.1398A>G p.I466M (on ENST00000256246; = p.I849M on NM_001350162.2) | Missense Mutation (SNP) | VAF 95/495 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as rs1329646843; called by muse, mutect2, varscan2
- TGM6 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 242/505 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.389); catalogued as rs769042038, COSV99171718; called by muse, mutect2, varscan2
- THSD7B | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 159/306 reads (52%) | catalogued as rs777485945, COSV55658875; called by muse, mutect2, varscan2
- TICRR | c.1104G>T p.E368D | Missense Mutation (SNP) | VAF 205/438 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1319886262, COSV51537912; called by muse, mutect2, varscan2
- TJP1 | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as rs768807966; called by muse, mutect2, varscan2
- TMCC2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 399/828 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201022917; called by muse, mutect2, varscan2
- TMEM121 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 510/1040 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs1189287802, COSV66796086; called by muse, mutect2, varscan2
- TMEM63C | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 216/491 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759011366, COSV53600834; called by muse, mutect2, varscan2
- TNKS2 | c.2102A>G p.H701R | Missense Mutation (SNP) | VAF 124/297 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757239643; called by muse, mutect2, varscan2
- TNN | c.3674C>T p.A1225V | Missense Mutation (SNP) | VAF 190/509 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV53424023; called by muse, mutect2, varscan2
- TNPO2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 312/638 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV63507627; called by muse, mutect2, varscan2
- TOMM20L | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 186/369 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1459257704; called by muse, mutect2, varscan2
- TOR4A | c.254T>A p.L85Q | Missense Mutation (SNP) | VAF 113/883 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV62626617; called by muse, mutect2, varscan2
- TOR4A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 140/1128 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs756370946; called by muse, mutect2, varscan2
- TP53I13 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 277/574 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as rs577200698; called by muse, mutect2, varscan2
- TPO | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 469/1008 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369225819; called by muse, mutect2, varscan2
- TRAF5 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 275/504 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs748492186, COSV54822757; called by muse, mutect2, varscan2
- TRAPPC12 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 184/365 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209116401, COSV60849843, COSV60851063; called by muse, mutect2, varscan2
- TRAPPC9 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 215/670 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66901683; called by muse, mutect2, varscan2
- TRIM32 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 298/609 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs765158423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM50 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 305/648 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.341); catalogued as rs370443781; called by muse, mutect2, varscan2
- TRIM9 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 168/395 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1431463984, COSV53612929; called by muse, mutect2, varscan2
- TRIO | c.8834C>T p.T2945M | Missense Mutation (SNP) | VAF 221/519 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs574639687; called by muse, mutect2, varscan2
- TRMT12 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 271/853 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100149202; called by muse, mutect2, varscan2
- TTN | c.100564C>A p.L33522M (on ENST00000591111; = p.L26098M on NM_003319.4) | Missense Mutation (SNP) | VAF 244/492 reads (50%) | PolyPhen benign (0.009); catalogued as COSV100634623; called by muse, mutect2, varscan2
- UBN2 | c.941del p.K314Rfs*11 | Frame Shift Del (DEL) | VAF 120/286 reads (42%) | catalogued as rs1427812488, COSV99943446; called by mutect2, pindel, varscan2
- UGT1A8 | c.364del p.S122Rfs*12 | Frame Shift Del (DEL) | VAF 120/336 reads (36%) | catalogued as rs762306873; called by mutect2, pindel, varscan2
- VPS13A | c.4936G>A p.V1646I | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs770575409; called by muse, mutect2, varscan2
- VPS13B | c.5608dup p.T1870Nfs*12 | Frame Shift Ins (INS) | VAF 146/544 reads (27%) | catalogued as rs1176397159; called by mutect2, pindel, varscan2
- VPS37D | c.748del p.H250Tfs*75 | Frame Shift Del (DEL) | VAF 52/175 reads (30%) | catalogued as rs1563540888; called by mutect2, pindel, varscan2
- WDFY2 | c.336G>A p.A112= | Splice Region (SNP) | VAF 157/323 reads (49%) | catalogued as rs1383576987, COSV53289278; called by muse, mutect2, varscan2
- WDFY3 | c.8309G>A p.R2770Q | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560564400; called by muse, mutect2, varscan2
- WDFY4 | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 205/481 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs747717433, COSV55441096; called by muse, mutect2, varscan2
- WDR77 | c.25dup p.L9Pfs*54 | Frame Shift Ins (INS) | VAF 105/295 reads (36%) | catalogued as rs769189971; called by mutect2, varscan2
- WDR90 | c.4165G>A p.E1389K | Missense Mutation (SNP) | VAF 208/438 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745634832, COSV53472386; called by muse, mutect2, varscan2
- WDR93 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 130/278 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs376704792, COSV99175872; called by muse, mutect2, varscan2
- WT1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 409/827 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs1554946595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWP2 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 202/523 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs371214769; called by muse, mutect2, varscan2
- XAB2 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 335/683 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372229800; called by muse, mutect2, varscan2
- YBX2 | c.239del p.P80Rfs*81 | Frame Shift Del (DEL) | VAF 334/826 reads (40%) | catalogued as rs1567605546, CM094250; called by pindel, varscan2
- ZACN | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 237/515 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV104401422; called by muse, mutect2, varscan2
- ZC3H18 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 397/848 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1350106436; called by muse, mutect2, varscan2
- ZDHHC5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 155/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1328910163, COSV54705570; called by muse, mutect2, varscan2
- ZFC3H1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 150/481 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.091); catalogued as rs766135294; called by muse, mutect2, varscan2
- ZFHX4 | c.1230del p.L411Cfs*4 | Frame Shift Del (DEL) | VAF 204/718 reads (28%) | catalogued as COSV99265992; called by mutect2, varscan2
- ZHX2 | c.427T>A p.L143I | Missense Mutation (SNP) | VAF 226/705 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.867); catalogued as COSV58716875; called by muse, mutect2, varscan2
- ZNF385B | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 302/636 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308267667, COSV69803498; called by muse, mutect2, varscan2
- ZNF561 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.228); catalogued as rs754290323, COSV100254523; called by muse, mutect2, varscan2
- ZNF57 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 256/544 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs150372606; called by muse, mutect2, varscan2
- ZNF596 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 196/683 reads (29%) | catalogued as rs145428583; called by muse, mutect2, varscan2
- ZNF672 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 100/824 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.851); catalogued as rs761742393, COSV60637876; called by muse, mutect2, varscan2
- ZNF7 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 267/851 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745767675, COSV57383197; called by muse, mutect2, varscan2
- ZNF710 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 257/532 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs372301042; called by muse, mutect2, varscan2
- ZNF837 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 325/930 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1427333773; called by muse, mutect2, varscan2
- ZNF878 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 194/423 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV104438550; called by mutect2, varscan2
- ZNFX1 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 276/567 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1230577367; called by muse, mutect2, varscan2
- ZSCAN1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 476/938 reads (51%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as rs546837948, COSV56603607; called by muse, mutect2, varscan2
- ZSCAN25 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 213/499 reads (43%) | catalogued as rs1562971601, COSV53553470; called by muse, mutect2, varscan2
- ZWINT | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 39/539 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59184996; called by muse, mutect2
- AASDH | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AATK | c.3686A>G p.K1229R (on ENST00000326724 / NM_001080395.3; = p.K1126R on NM_004920.2) | Missense Mutation (SNP) | VAF 68/587 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC006059.2 | c.1291A>C p.T431P | Missense Mutation (SNP) | VAF 243/466 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AC127029.3 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 154/603 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ACAD10 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 125/521 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACKR3 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ACTB | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 194/388 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ACTL10 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 412/837 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ACTL9 | c.1076_1078del p.L359del | In Frame Del (DEL) | VAF 288/677 reads (43%) | called by pindel, varscan2
- ACVR2A | c.1309_1310del p.K437Efs*19 | Frame Shift Del (DEL) | VAF 176/475 reads (37%) | called by pindel, varscan2
- ADA2 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM18 | c.1698A>C p.Q566H | Missense Mutation (SNP) | VAF 201/692 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAM20 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 64/507 reads (13%) | called by muse, mutect2, varscan2
- ADCY6 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ADGRG4 | c.4720C>A p.P1574T | Missense Mutation (SNP) | VAF 257/520 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL1 | c.2661dup p.L888Afs*20 (on ENST00000340736 / NM_001008701.3; = p.L883Afs*20 on NM_014921.5) | Frame Shift Ins (INS) | VAF 220/751 reads (29%) | called by mutect2, pindel, varscan2
- ADRA2C | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 181/328 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK | c.6094A>G p.I2032V | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP9 | c.3854C>T p.T1285I | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP9 | c.6289del p.M2097* (on ENST00000359028; = p.M2065* on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 114/282 reads (40%) | called by mutect2, pindel, varscan2
- AKR1B10 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 187/435 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- AL645922.1 | c.1814G>A p.C605Y | Missense Mutation (SNP) | VAF 233/487 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AL772284.1 | c.212del p.G71Vfs*12 | Frame Shift Del (DEL) | VAF 262/730 reads (36%) | called by pindel, varscan2
- ALDH18A1 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 211/477 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALOX15B | c.1692T>A p.C564* | Nonsense Mutation (SNP) | VAF 57/430 reads (13%) | called by muse, mutect2, varscan2
- AMBP | c.162dup p.W55Lfs*38 | Frame Shift Ins (INS) | VAF 192/568 reads (34%) | called by pindel, varscan2
- AMBRA1 | c.1405G>T p.G469W (on ENST00000458649 / NM_001367468.1; = p.G379W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 305/607 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANK2 | c.4212del p.F1404Lfs*28 | Frame Shift Del (DEL) | VAF 157/433 reads (36%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.4215del p.K1405Nfs*10 | Frame Shift Del (DEL) | VAF 137/340 reads (40%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.5852C>T p.A1951V | Missense Mutation (SNP) | VAF 109/866 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30BL | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 147/320 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 71/220 reads (32%) | called by mutect2, varscan2
- APOL6 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 270/615 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ARHGAP11A | c.1576A>G p.N526D | Missense Mutation (SNP) | VAF 253/511 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP15 | c.1097T>A p.L366H | Missense Mutation (SNP) | VAF 173/355 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP45 | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 245/522 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ARID3C | c.725del p.P242Lfs*40 | Frame Shift Del (DEL) | VAF 95/857 reads (11%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.1120A>C p.S374R | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ARX | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 300/622 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ASCL5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 232/588 reads (39%) | SIFT tolerated (0.15); called by mutect2, varscan2
- ASH1L | c.4002dup p.D1336Rfs*10 | Frame Shift Ins (INS) | VAF 82/349 reads (23%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2342del p.P781Rfs*32 | Frame Shift Del (DEL) | VAF 61/533 reads (11%) | called by mutect2, pindel, varscan2
- ATAD2B | c.1392del p.V465Wfs*12 | Frame Shift Del (DEL) | VAF 261/598 reads (44%) | called by mutect2, pindel, varscan2
- ATG2A | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 358/830 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- AVPR1B | c.418del p.L140Cfs*38 | Frame Shift Del (DEL) | VAF 307/803 reads (38%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.36del p.K12Nfs*4 | Frame Shift Del (DEL) | VAF 126/316 reads (40%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.1004G>A p.S335N | Missense Mutation (SNP) | VAF 526/1037 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- BCL2L13 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 131/359 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- BCL9L | c.308del p.P103Lfs*9 | Frame Shift Del (DEL) | VAF 318/770 reads (41%) | called by mutect2, pindel, varscan2
- BCORL1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 401/855 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BCR | c.252del p.D85Tfs*94 | Frame Shift Del (DEL) | VAF 472/1110 reads (43%) | called by mutect2, pindel, varscan2
- BDH1 | c.512dup p.T172Hfs*54 | Frame Shift Ins (INS) | VAF 311/788 reads (39%) | called by mutect2, pindel, varscan2
- BMP8B | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 282/608 reads (46%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- BNC2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 153/349 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- BOD1L1 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 192/399 reads (48%) | called by muse, mutect2, varscan2
- BRCA2 | c.5764G>A p.A1922T | Missense Mutation (SNP) | VAF 192/404 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- BRMS1 | c.321del p.L108Cfs*22 | Frame Shift Del (DEL) | VAF 192/394 reads (49%) | called by mutect2, varscan2
- BTBD3 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 173/363 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- BTN3A2 | c.878T>C p.M293T | Missense Mutation (SNP) | VAF 118/253 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BX255925.3 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 120/987 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- C10orf90 | c.1657C>A p.P553T | Missense Mutation (SNP) | VAF 36/650 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.037); called by muse, mutect2
- C11orf87 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 276/800 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- C1QTNF12 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 323/699 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- C2orf92 | c.765del p.K255Nfs*5 | Frame Shift Del (DEL) | VAF 215/538 reads (40%) | called by mutect2, pindel, varscan2
- C8G | c.96del p.I33Sfs*116 | Frame Shift Del (DEL) | VAF 276/857 reads (32%) | called by pindel, varscan2
- CACNA1B | c.5273C>T p.P1758L | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1I | c.3267del p.H1091Mfs*43 | Frame Shift Del (DEL) | VAF 349/842 reads (41%) | called by mutect2, pindel, varscan2
- CACNA1I | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 462/909 reads (51%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, varscan2
- CAMK2A | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMTA1 | c.4904del p.K1635Sfs*9 | Frame Shift Del (DEL) | VAF 200/462 reads (43%) | called by mutect2, pindel, varscan2
- CAPN12 | c.1188_1190del p.D397del | In Frame Del (DEL) | VAF 43/461 reads (9%) | called by mutect2, pindel
- CBX3 | c.31del p.M11Wfs*26 | Frame Shift Del (DEL) | VAF 147/372 reads (40%) | called by mutect2, pindel, varscan2
- CCNG1 | c.338G>T p.R113M | Missense Mutation (SNP) | VAF 64/526 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCT5 | c.1087T>A p.S363T | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDC42BPG | c.2435T>C p.L812P | Missense Mutation (SNP) | VAF 199/416 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDC42EP5 | c.94C>T p.H32Y | Missense Mutation (SNP) | VAF 404/869 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- CDH2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 137/297 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH3 | c.651G>T p.Q217H | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDKL4 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDV3 | c.273del p.E92Rfs*14 | Frame Shift Del (DEL) | VAF 180/418 reads (43%) | called by mutect2, pindel, varscan2
- CEACAM19 | c.876dup p.Y293Lfs*46 | Frame Shift Ins (INS) | VAF 194/521 reads (37%) | called by mutect2, pindel, varscan2
- CEND1 | c.134del p.P45Rfs*34 | Frame Shift Del (DEL) | VAF 437/1093 reads (40%) | called by mutect2, pindel, varscan2
- CENPE | c.5986del p.I1996Lfs*7 | Frame Shift Del (DEL) | VAF 143/382 reads (37%) | called by pindel, varscan2
- CEP250 | c.4813C>T p.Q1605* | Nonsense Mutation (SNP) | VAF 229/458 reads (50%) | called by muse, mutect2, varscan2
- CEP350 | c.5174del p.K1725Nfs*24 | Frame Shift Del (DEL) | VAF 126/290 reads (43%) | called by mutect2, pindel, varscan2
- CERT1 | c.661A>G p.S221G (on ENST00000405807 / NM_001130105.1; = p.S93G on NM_005713.3) | Missense Mutation (SNP) | VAF 141/311 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CFAP20DC | c.727A>G p.N243D (on ENST00000482387 / NM_001351530.2; = p.N118D on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 107/277 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CFAP52 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 135/299 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CHD3 | c.1940A>G p.Y647C | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHRM5 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 263/573 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CHST14 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 412/833 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- CHST9 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 90/248 reads (36%) | called by muse, mutect2, varscan2
- CLCN1 | c.263T>C p.V88A | Missense Mutation (SNP) | VAF 131/268 reads (49%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLEC4E | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 145/354 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CLEC9A | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CNOT11 | c.1336-4_1354delinsCAGAATCGGTTGGTGCGTCT p.X446_splice | Splice Site (DEL) | VAF 62/314 reads (20%) | called by pindel, varscan2*
- CNTN4 | c.1477G>T p.V493L | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COBL | c.3267del p.F1089Lfs*25 | Frame Shift Del (DEL) | VAF 288/669 reads (43%) | called by mutect2, pindel, varscan2
- COL11A2 | c.3803C>A p.P1268H (on ENST00000341947 / NM_080680.3; = p.P1161H on NM_080679.2) | Missense Mutation (SNP) | VAF 241/551 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL4A1 | c.1763dup p.G589Wfs*11 | Frame Shift Ins (INS) | VAF 219/536 reads (41%) | called by mutect2, pindel, varscan2
- COL6A5 | c.5613del p.F1871Lfs*50 (on ENST00000312481; = p.F1867Lfs*50 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/594 reads (10%) | called by mutect2, pindel, varscan2
- COPRS | c.37del p.A13Pfs*43 | Frame Shift Del (DEL) | VAF 363/741 reads (49%) | called by mutect2, varscan2
- CPEB1 | c.123del p.F41Lfs*10 | Frame Shift Del (DEL) | VAF 191/471 reads (41%) | called by mutect2, pindel, varscan2
- CROCC2 | c.1150del p.H384Ifs*26 | Frame Shift Del (DEL) | VAF 396/944 reads (42%) | called by mutect2, pindel, varscan2
- CRTC1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 228/496 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, varscan2
- CSF3R | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 247/508 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSTF1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 308/590 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CTDSPL2 | c.1367G>T p.R456I | Missense Mutation (SNP) | VAF 321/322 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CTNNA2 | c.1559A>G p.D520G | Missense Mutation (SNP) | VAF 40/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTTNBP2NL | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 302/625 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUBN | c.9252T>A p.D3084E | Missense Mutation (SNP) | VAF 160/323 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CXCR5 | c.129del p.L45Sfs*22 | Frame Shift Del (DEL) | VAF 113/726 reads (16%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.3809T>C p.I1270T (on ENST00000616178 / NM_001291722.2; = p.I1245T on NM_014376.4) | Missense Mutation (SNP) | VAF 165/497 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CYP11B2 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 56/598 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- CYP26C1 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 51/593 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CYP26C1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 335/994 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F3 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 217/402 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DACT1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 72/583 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX17 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 125/435 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- DDX28 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 354/807 reads (44%) | called by muse, mutect2, varscan2
- DDX56 | c.1362_1364del p.L455del | In Frame Del (DEL) | VAF 194/415 reads (47%) | called by mutect2, pindel, varscan2
- DHX8 | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMTN | c.364del p.R122Gfs*109 | Frame Shift Del (DEL) | VAF 310/984 reads (32%) | called by mutect2, varscan2
- DNAH1 | c.8452A>G p.I2818V | Missense Mutation (SNP) | VAF 219/544 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH8 | c.9786dup p.V3263Sfs*23 | Frame Shift Ins (INS) | VAF 209/513 reads (41%) | called by mutect2, pindel, varscan2
- DNAJC11 | c.1362G>T p.E454D | Missense Mutation (SNP) | VAF 172/392 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by mutect2, varscan2
- DNAJC13 | c.3983C>T p.A1328V | Missense Mutation (SNP) | VAF 127/340 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAJC5 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- DOCK11 | c.848del p.K283Rfs*4 | Frame Shift Del (DEL) | VAF 109/419 reads (26%) | called by mutect2, pindel, varscan2
- DOCK4 | c.779T>C p.F260S | Missense Mutation (SNP) | VAF 134/272 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOT1L | c.2959C>A p.H987N | Missense Mutation (SNP) | VAF 129/974 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DST | c.20167A>G p.R6723G (on ENST00000361203 / NM_001374722.1; = p.R4420G on NM_015548.5) | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- DTX2 | c.1196del p.N399Tfs*6 | Frame Shift Del (DEL) | VAF 55/63 reads (87%) | called by mutect2, varscan2
- ECPAS | c.5214del p.Q1739Rfs*3 | Frame Shift Del (DEL) | VAF 141/322 reads (44%) | called by mutect2, pindel, varscan2
- ELL2 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 76/187 reads (41%) | called by muse, mutect2, varscan2
- ENAM | c.1048del p.Y350Tfs*22 | Frame Shift Del (DEL) | VAF 212/500 reads (42%) | called by mutect2, pindel, varscan2
- EP400 | c.3830A>G p.E1277G | Missense Mutation (SNP) | VAF 233/465 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 259/516 reads (50%) | called by mutect2, varscan2
- EPN1 | c.1259G>A p.S420N (on ENST00000270460 / NM_001321263.1; = p.S394N on NM_013333.3) | Missense Mutation (SNP) | VAF 202/442 reads (46%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- EPRS1 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ERBB4 | c.1869A>G p.Q623= | Splice Region (SNP) | VAF 171/341 reads (50%) | called by muse, mutect2, varscan2
- ERVMER34-1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, varscan2
- ERVMER34-1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 214/417 reads (51%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, varscan2
- ESRP2 | c.75dup p.W26Lfs*36 | Frame Shift Ins (INS) | VAF 369/919 reads (40%) | called by mutect2, pindel, varscan2
- EWSR1 | c.1385A>C p.E462A | Missense Mutation (SNP) | VAF 256/524 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXOC3L1 | c.1431dup p.K478Efs*81 | Frame Shift Ins (INS) | VAF 232/567 reads (41%) | called by mutect2, pindel, varscan2
- EXOC3L2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 330/592 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FAAP100 | c.2051G>T p.R684L | Missense Mutation (SNP) | VAF 405/848 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM207A | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 248/541 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM71E2 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 69/535 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM76B | c.147A>C p.Q49H | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM83H | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 139/1682 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2
- FAM9A | c.476_477del p.K159Tfs*8 | Frame Shift Del (DEL) | VAF 108/270 reads (40%) | called by mutect2, varscan2
- FAP | c.804T>A p.D268E | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- FASN | c.6060_6062del p.S2021del | In Frame Del (DEL) | VAF 210/497 reads (42%) | called by pindel, varscan2
- FAT2 | c.12709G>A p.A4237T | Missense Mutation (SNP) | VAF 287/638 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FBXO10 | c.689del p.N230Tfs*27 | Frame Shift Del (DEL) | VAF 261/624 reads (42%) | called by mutect2, pindel, varscan2
- FCRL4 | c.603G>T p.Q201H | Missense Mutation (SNP) | VAF 201/399 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FEM1C | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 134/321 reads (42%) | called by muse, mutect2, varscan2
- FGB | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 166/379 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FIGNL2 | c.7T>G p.W3G | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FOXK1 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 76/681 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.4411G>T p.G1471C | Missense Mutation (SNP) | VAF 274/531 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2C | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 203/1280 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FRMPD1 | c.4324del p.V1442Lfs*35 | Frame Shift Del (DEL) | VAF 326/765 reads (43%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 290/752 reads (39%) | called by mutect2, pindel, varscan2
- GAD1 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 207/423 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAS2L2 | c.1008del p.T337Pfs*25 | Frame Shift Del (DEL) | VAF 218/617 reads (35%) | called by pindel, varscan2
- GBF1 | c.1648T>C p.S550P (on ENST00000369983 / NM_001377137.1; = p.S549P on NM_004193.3) | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- GCC2 | c.2106del p.K702Nfs*3 | Frame Shift Del (DEL) | VAF 114/266 reads (43%) | called by mutect2, varscan2
- GEMIN5 | c.1452del p.M485Cfs*58 | Frame Shift Del (DEL) | VAF 94/266 reads (35%) | called by mutect2, pindel, varscan2
- GFRA4 | c.562C>T p.R188C (on ENST00000319242 / NM_145762.3; = p.R161= on NM_022139.4) | Missense Mutation (SNP) | VAF 360/738 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GGTLC1 | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 221/437 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GK3P | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 203/481 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLI2 | c.2495C>T p.A832V (on ENST00000361492 / NM_001374353.1; = p.A849V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 479/997 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GNAI1 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 59/419 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA6L7 | c.1652C>A p.P551H | Missense Mutation (SNP) | VAF 181/359 reads (50%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- GOLGA8F | c.712dup p.I238Nfs*3 (on ENST00000526619; = p.I444Nfs*3 on NM_001350920.2) | Frame Shift Ins (INS) | VAF 110/520 reads (21%) | called by mutect2, pindel, varscan2
- GPR4 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 264/543 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GPR50 | c.857A>C p.N286T | Missense Mutation (SNP) | VAF 88/744 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GRIK5 | c.2684C>T p.A895V | Missense Mutation (SNP) | VAF 456/900 reads (51%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GRM8 | c.644G>C p.W215S | Missense Mutation (SNP) | VAF 277/642 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSDMA | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2
- GTF3C1 | c.3827G>T p.C1276F | Missense Mutation (SNP) | VAF 75/555 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTPBP8 | c.616del p.T206Qfs*6 | Frame Shift Del (DEL) | VAF 120/322 reads (37%) | called by mutect2, pindel, varscan2
- GUCY1A2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 376/687 reads (55%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- HACD3 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HAUS2 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- HCFC1 | c.5293dup p.Q1765Pfs*50 | Frame Shift Ins (INS) | VAF 314/751 reads (42%) | called by mutect2, pindel, varscan2
- HDAC2 | c.1375dup p.T459Nfs*4 | Frame Shift Ins (INS) | VAF 87/194 reads (45%) | called by mutect2, varscan2
- HECTD4 | c.3256C>A p.P1086T | Missense Mutation (SNP) | VAF 192/375 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- HECW2 | c.2210G>A p.W737* | Nonsense Mutation (SNP) | VAF 365/769 reads (47%) | called by muse, mutect2, varscan2
- HERC2 | c.3588del p.F1196Lfs*12 | Frame Shift Del (DEL) | VAF 101/252 reads (40%) | called by mutect2, pindel, varscan2
- HERC5 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 98/706 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HGSNAT | c.1670T>C p.L557P | Missense Mutation (SNP) | VAF 183/568 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HIC2 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 95/884 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- HIPK1 | c.2381G>T p.R794M | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HLA-B | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 200/575 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.13271C>A p.S4424Y | Missense Mutation (SNP) | VAF 93/678 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HNF4A | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 234/468 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HNRNPUL2 | c.2190_2191insA p.Q731Tfs*54 | Frame Shift Ins (INS) | VAF 146/397 reads (37%) | called by mutect2, pindel, varscan2
- HOOK2 | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 197/459 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPA12B | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 484/982 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HSPA1A | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 198/579 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HSPA2 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 70/581 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ICAM3 | c.1621del p.E541Kfs*? | Frame Shift Del (DEL) | VAF 197/458 reads (43%) | called by mutect2, pindel, varscan2
- ICAM4 | c.361del p.T121Hfs*17 | Frame Shift Del (DEL) | VAF 273/718 reads (38%) | called by mutect2, pindel, varscan2
- ICMT | c.803_805del p.K268del | In Frame Del (DEL) | VAF 158/360 reads (44%) | called by pindel, varscan2
- IDH2 | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 303/602 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- IDI2 | c.77A>C p.E26A | Missense Mutation (SNP) | VAF 200/546 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- IFNGR1 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, varscan2
- IFNL3 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 279/574 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGFBP4 | c.665A>G p.Q222R | Missense Mutation (SNP) | VAF 254/566 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- IGHV3-23 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 110/569 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IL12A | c.128T>A p.L43H | Missense Mutation (SNP) | VAF 177/328 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IL16 | c.1857_1858dup p.N620Rfs*67 | Frame Shift Ins (INS) | VAF 120/398 reads (30%) | called by mutect2, varscan2
- IL17RA | c.2199del p.M734Wfs*11 | Frame Shift Del (DEL) | VAF 84/946 reads (9%) | called by mutect2, pindel
- IL1RAPL1 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 259/607 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IL1RL1 | c.1054del p.M352Cfs*13 | Frame Shift Del (DEL) | VAF 133/350 reads (38%) | called by mutect2, pindel, varscan2
- INAVA | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 389/756 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- INHBA | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 19/543 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- INSC | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 221/462 reads (48%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS4 | c.2003T>C p.L668P | Missense Mutation (SNP) | VAF 40/407 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- IQGAP2 | c.1871C>T p.T624I | Missense Mutation (SNP) | VAF 104/389 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- IRF9 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 308/638 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IRX5 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 312/684 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ITGAM | c.3350del p.G1117Dfs*25 (on ENST00000648685 / NM_001145808.2; = p.G1116Dfs*25 on NM_000632.4) | Frame Shift Del (DEL) | VAF 254/635 reads (40%) | called by mutect2, pindel, varscan2
712 further variants in this file (347 protein-altering or splice-affecting, 306 silent, 59 other) are not listed here.
